Somatic mutation profile of tumor specimen 0DZK5F from CCDI case PBCUDL, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female.
Specimen 0DZK5F: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64f78048-ee1b-420c-b894-5591f2ac6643.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DZK5K (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/276a239d-c65d-40bd-88e5-600ac3ecd814

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAZ2B | c.4547C>T p.T1516M | Missense Mutation (SNP) | VAF 135/386 reads (35%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.765); catalogued as rs1444509662, COSV58607797; called by muse, mutect2, varscan2
- PKD1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 63/228 reads (28%) | SIFT tolerated (0.91); PolyPhen benign (0.003); catalogued as rs769788441, CM085643; called by muse, mutect2, varscan2
